TCGA case TCGA-HM-A3JK — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7c4cd55f-750e-4941-a9f3-0632a75d6531

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 64.7 years (23,618 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IIA2; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 51; Lymphatic invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 79 days; Days to treatment end: 107 days; Number of cycles: 5; Treatment dose: 350 mg; Prescribed dose: 70; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 79 days; Days to treatment end: 113 days; Treatment dose: 4,500 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.

Follow-up (14 entries)
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: PET; Imaging result: Negative; Imaging anatomic site: Cervix Uteri; Imaging findings: Extra-Pelvic Metastatic Disease; Imaging suv: 13.8.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 17 (preoperative): Days to imaging: 17 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 21 (preoperative): ECOG performance status: 0.
- Days to follow up: 168 days; Disease response: Tumor Free.
- Days to follow up: 351 days; Disease response: Tumor Free.
- Days to follow up: 632 days (1.7 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 94 kg; Height: 165 cm; BMI: 34.5.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2008.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HM-A3JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 220 mg.
  Slide TCGA-HM-A3JK-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HM-A3JK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HM-A3JK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 0; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 0; Tobacco smoking history indicator: 4; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Pelvic extension comment: carcinoma involves all sections of the cervix with direct extension into the myometrial wall, parametrial tissues and upper vagina; Lymph nodes examined: Yes; Lymphovascular invasion: Absent.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation therapy xrt type: 3D conformal.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent dose: 70 mg; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 632 days; disease-specific survival: no event (censored), 632 days; disease-free interval: no event (censored), 632 days; progression-free interval: no event (censored), 632 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HM-A3JK-01A-11D-A21P-01): tumor purity 0.43, ploidy 3.37, whole-genome doublings 1.
